Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A8XE, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A8XE-01A (Primary Tumor).

ICD-O-3
Oligodendroglioma, grade II
Site: ^{CSCF}Supratentorial brain ^{9450/3}NAS
^{path}Insula C71.0
C71.0
Jw 11/29/14

Nature of material: Brain

Biopsy number:

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Received, in formalin, twenty-four irregular pieces of softening and brown-blackish tissue, weighing 1.0 g together with measurements ranging from 0.5 x 0.4 x 0.3 cm to 1.6 x 0.8 x 0.4 cm.

MICROSCOPY

Histological sections stained with H & E show fragments of brain parenchyma infiltrated by glial neoplasm, with moderate and high cellularity, represented by small cells with round and monotonous nuclei, sometimes with dense, sometimes with more dispersed cromatin, with frequent perinuclear halos. Many of the neoplastic cells exhibit moderate amount of eosinophilic, dense and homogeneous cytoplasm (minigemistocysts). The matrix is fibrillar and delicate, with microcystic degeneration and myxoid material deposition. The vascular capillary consists of simple, often curved capillaries, with no signs of microvascular proliferation. There are no areas of necrosis or mitotic figures (in 50 high-power fields).

DIAGNOSTIC

Biopsy product of insular lesion (laterality not reported):

Glial neoplasm of low-grade (II), according to the classification of WHO (2007).

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

DESCRIPTION OF THE REPORT SUPPLEMENT

This case has been discussed in conjunction with _____, having been considered a glial neoplasm of pure oligodendroglial component and due to absence of microvascular proliferation, mitotic activity and necrosis, grade II.

Conclusion:

-Oligodendroglioma, grade II, according to the classification of WHO (2007).

Criteria	Jw 11/8/13	res	yes
H.P.A.A. Discrepancy			
Qual/Synthesis Primary site			
Critic Is (circle):	QUALIFIED	C-51, C-116D	

Source: NCI Genomic Data Commons file 1c3bfb3e-482d-4abc-9425-ee6e38448358 (TCGA-TQ-A8XE.431037B9-36D3-4978-AEED-F316933DC782.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).